Gene-level copy-number profile of tumor specimen TCGA-NC-A5HO-01A from TCGA case TCGA-NC-A5HO, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.3 years (25,694 days).
Specimen TCGA-NC-A5HO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.87344a19-6284-42aa-891e-f45b2685a790.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/67fd9ce7-b3d4-4d8e-b44a-a63fc475ff57

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 2: 23,213; copy number 3: 3,389; copy number 4: 28,951; copy number 5: 920; copy number 6: 2,050; copy number 7: 90; copy number 8: 45; copy number 9: 593; copy number 10: 468; copy number 15: 6; copy number 22: 79.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HO-01A-11D-A26L-01): tumor purity 0.63, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:80,024,737–80,145,359, 9 genes: C1DP3, C1DP2, C1DP4, TMEM254-AS1, AL356095.3, TMEM254, AL356095.2, RPL22P18, PLAC9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,146 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:179,101,678–180,007,297, 9 genes, copy number 9: SESTD1, AC093911.1, RAD52P1, ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22.
- chr3:143,265,222–149,226,334, 64 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr3:149,761,100–149,968,385, 1 gene, copy number 10 (within-gene range 7–10): ANKUB1.
- chr3:149,812,770–198,222,513, 860 genes, copy number 9–15 (within-gene range 7–15) (broad region; genes not listed).
- chr11:69,048,932–69,162,440, 2 genes, copy number 22 (within-gene range 4–22): TPCN2, AP003071.5.
- chr11:69,103,493–71,821,548, 77 genes, copy number 22 (broad region; genes not listed).
- chr14:36,054,197–41,904,549, 76 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr16:5,239,802–7,713,340, 1 gene, copy number 9 (within-gene range 2–9): RBFOX1.
- chr16:6,573,767–10,227,581, 56 genes, copy number 9: AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2, TMEM114, AC138420.1, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195, AC007221.1, RNA5SP403, RNA5SP404, AC007218.1, GRIN2A, AC007218.2, AC007218.3, AC133565.1, IMPDH1P11, AC022168.1, RN7SL493P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
